Gene-level copy-number profile of tumor specimen TCGA-FD-A6TH-01A from TCGA case TCGA-FD-A6TH, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 63.6 years (23,236 days).
Specimen TCGA-FD-A6TH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.c1b58d29-aba8-4324-818b-ec1a57a50062.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A6TH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7fbe9217-cd92-4b94-a3b2-46b5baf320d2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 10,456; copy number 3: 25,284; copy number 4: 11,210; copy number 5: 8,970; copy number 6: 2,035; copy number 7: 1,448; copy number 9: 148; copy number 10: 111; copy number 11: 68; copy number 13: 15; copy number 17: 1; copy number 22: 69.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A6TH-01A-11D-A32A-01): tumor purity 0.77, ploidy 2.96, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,860 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–15,496,353, 276 genes, copy number 7–22 (broad region; genes not listed).
- chr5:15,602,189–15,619,109, 1 gene, copy number 7: CTD-2350J17.1.
- chr12:40,554,161–40,554,267, 1 gene, copy number 17: RNU6-713P.
- chr13:18,467,172–43,893,932, 496 genes, copy number 7 (broad region; genes not listed).
- chr13:43,894,725–43,895,182, 1 gene, copy number 7: AL512506.2.
- chr13:51,908,218–114,337,626, 716 genes, copy number 7 (broad region; genes not listed).
- chr14:21,563,819–23,645,639, 213 genes, copy number 7–11 (broad region; genes not listed).
- chr18:3,377,916–5,989,369, 42 genes, copy number 10–11: RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66, DLGAP1-AS5, AP005208.1, ELOCP27, AP005203.1, PPIAP14, LINC01892, BOD1P2, AKAIN1, AP005380.1, AP001496.4, AP001496.2, LINC00526, LINC00667, AP001496.3, ZBTB14, AP001496.1, AP005671.1, EPB41L3, AP005059.2, AP005059.1, MIR3976HG, MIR3976, TMEM200C, AP001021.1.
- chr18:5,956,101–5,960,785, 1 gene, copy number 10: AP001021.2.
- chr19:27,638,483–28,727,777, 26 genes, copy number 7 (within-gene range 6–7): ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1.
- chr19:55,452,985–56,922,213, 87 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
